Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3Y9, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3Y9-01A (Primary Tumor).

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus *Distal, per TSS*

Tumor size: 3.5 x 4.5 x 1.2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adjacent structures (specify)

Lymph nodes: 0/12 positive for metastasis (Regional 0/12)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

*Carcinoma, Squamous cell, NOS
8070/3*

Site:

*CRCF - esophagus, distal third
C15.5*

Path: esophagus, NOS

*C15.9 6/6/12
20*

W 5/24/12

Source: NCI Genomic Data Commons file c2e182fb-9649-447e-87d6-e1a9c6567858 (TCGA-IG-A3Y9.45AB6DDD-AC49-4258-B31C-F4ED42207DA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).